Gene-level copy-number profile of tumor specimen TCGA-BT-A42E-01A from TCGA case TCGA-BT-A42E, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 74.0 years (27,045 days).
Specimen TCGA-BT-A42E-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.777a6a84-98c4-4d04-b600-ad3f8c8caec2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BT-A42E-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9848f0be-b9dc-4cc3-a09a-9b6b90f98c2d

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 115; copy number 1: 760; copy number 2: 18,896; copy number 3: 18,962; copy number 4: 14,126; copy number 5: 5,742; copy number 6: 346; copy number 7: 242; copy number 8: 284; copy number 9: 49; copy number 11: 136; copy number 13: 30; copy number 18: 22; copy number 21: 71; copy number 42: 32.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BT-A42E-01A-11D-A23T-01): tumor purity 0.48, ploidy 3.17, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 115 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:19,409,009–24,088,051, 91 genes (within-gene range 0–3) (broad region; genes not listed).
- chr18:50,795,120–53,535,903, 24 genes (within-gene range 0–1): MRO, HNRNPA3P16, RPL17P46, ME2, Y_RNA, ELAC1, AC091551.1, SMAD4, SRSF10P1, MEX3C, RNU1-46P, LINC01630, SS18L2P2, AC109315.1, RSL24D1P9, AC027216.1, RPS8P3, AC016383.3, AC016383.2, AC016383.1, DCC, AC011155.1, VN1R76P, MIR4528.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 866 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:37,350,934–41,242,154, 136 genes, copy number 11 (within-gene range 2–11) (broad region; genes not listed).
- chr2:103,275,904–104,733,362, 24 genes, copy number 9: AC010881.1, AC011593.1, CRLF3P1, AC018880.1, CAPZBP1, AC013727.1, AC013727.2, LINC01965, AC013727.3, AC096554.1, AHCYP3, AC068535.1, LINC01831, AC068535.2, LINC01102, LINC01103, AC013402.2, AC013402.3, AC068057.3, AC013402.1, RPL23AP27, AC068057.1, AC068057.2, SNORA72.
- chr2:107,754,112–117,539,464, 207 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr4:61,201,258–62,078,335, 1 gene, copy number 7 (within-gene range 5–7): ADGRL3.
- chr4:61,775,449–65,241,814, 31 genes, copy number 7: AC108161.1, Y_RNA, ADGRL3-AS1, RPS15AP17, AC007511.1, RPL21P47, AC105313.1, AC074087.2, AC074087.1, HMGN1P11, EXOC5P1, AC097491.1, LARP1BP1, AC093730.1, TECRL, RNU6-191P, DPP3P1, MTCO3P27, MTCYBP16, MTND6P16, MTND5P13, MTND4LP31, MTND3P24, MTCO3P28, AC104689.1, AC104689.2, LINC02232, AC107058.1, EFL1P2, AC096754.1, LINC02835.
- chr8:37,067,441–37,406,724, 4 genes, copy number 9: AC092818.1, SMARCE1P4, AC091182.1, AC091182.2.
- chr8:39,860,219–41,896,762, 41 genes, copy number 8 (within-gene range 4–8): AP005902.2, AP005902.1, IDO1, AC007991.3, AC007991.2, AC007991.4, IDO2, AC007991.1, AC087518.1, LINC02866, TCIM, AC022733.1, SIRLNT, AC105999.1, AC010857.1, ZMAT4, AC048387.1, RNU6-356P, SFRP1, MIR548AO, RPS29P2, AC104393.1, RNU6-895P, SNORD65B, AC016868.1, GOLGA7, AC009630.1, KRT18P37, GINS4, AC009630.2, AC009630.4, GPAT4, AC009630.3, NKX6-3, ANK1, MIR486-1, MIR486-2, AC113133.1, Y_RNA, AC027702.1, RN7SL149P.
- chr11:48,216,810–48,489,780, 13 genes, copy number 9: OR4B1, OR4B2P, OR4X2, OR4X1, OR4S1, OR4C3, OR4C4P, OR4C5, OR4C2P, OR4C10P, OR4C9P, OR4R1P, OR4A47.
- chr11:99,020,949–100,358,885, 1 gene, copy number 42 (within-gene range 4–42): CNTN5.
- chr11:100,336,856–108,222,638, 124 genes, copy number 13–42 (broad region; genes not listed).
- chr11:108,229,503–108,229,604, 1 gene, copy number 18: Y_RNA.
- chr14:71,179,053–82,430,156, 243 genes, copy number 8 (broad region; genes not listed).
- chr15:26,115,726–26,970,385, 10 genes, copy number 7–9: LINC00929, AC012060.1, LINC02248, AC009878.2, GABRB3, AC009878.1, AC011196.1, AC135999.1, GABRA5, TVP23BP1.
- chr15:27,038,978–27,161,319, 1 gene, copy number 9 (within-gene range 2–9): GABRG3-AS1.
- chr22:20,859,007–21,227,637, 29 genes, copy number 21: SNAP29, AC007308.1, CRKL, LINC01637, AIFM3, AC002470.2, AC002470.1, LZTR1, THAP7, THAP7-AS1, AC002472.2, TUBA3FP, P2RX6, AC002472.3, SLC7A4, AC002472.1, MIR649, P2RX6P, LRRC74B, TUBA3GP, AC002472.4, BCRP2, AP000550.1, POM121L7P, E2F6P2, FAM230B, AP000550.2, FAM247A, GGT2.

Autosomal genes at a single copy (total copy number 1): 414. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
